Somatic mutation profile of tumor specimen C3L-02967-01 (aliquot CPT0218490006) from CPTAC case C3L-02967, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G1; Age at diagnosis: 74.4 years (27,172 days).
Specimen C3L-02967-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f33bc6-3b24-41ab-833a-6df21b2a1047.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02967-31 (Blood Derived Normal), aliquot CPT0219900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9a7e232-bb1f-4b30-81a4-d1aedbd31ffa

The open-access MAF lists 83 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Intron 7, Splice Site 3, 3'UTR 2, RNA 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as rs1057520606, CM002109, COSV58820855, COSV58827158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLEC14A | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV60563375; called by muse, mutect2
- COL14A1 | c.4540C>A p.Q1514K | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.965); catalogued as COSV52854274, COSV52862309; called by muse, mutect2, varscan2
- CPA4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 103/586 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs764563230, COSV99745227; called by muse, varscan2
- CTR9 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1391585643, COSV63728784; called by muse, mutect2, varscan2
- FAT4 | c.7552G>T p.D2518Y | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104405870; called by muse, mutect2, varscan2
- GAA | c.1274C>A p.P425Q | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765235868; called by muse, mutect2, varscan2
- KEAP1 | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV50634336; called by muse, mutect2, varscan2
- LCT | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 63/487 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748907176, COSV51543639; called by muse, mutect2, varscan2
- LZTR1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 32/259 reads (12%) | catalogued as COSV53147766; called by muse, mutect2, varscan2
- NCOA7 | c.1528A>T p.T510S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1406504030; called by muse, mutect2, varscan2
- PAH | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as CM1511426; called by muse, mutect2, varscan2
- PARP4 | c.2758+1G>T p.X920_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67961256; called by muse, mutect2, varscan2
- PLA2G4A | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.137); catalogued as rs1312455416, COSV66554344, COSV66555613; called by muse, mutect2
- RGS2 | c.190dup p.S64Kfs*12 | Frame Shift Ins (INS) | VAF 74/660 reads (11%) | catalogued as rs775439827; called by mutect2, varscan2
- S100PBP | c.995A>G p.H332R | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs1170226854, COSV100758346; called by muse, mutect2, varscan2
- SAP130 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.56); catalogued as rs540354086, COSV52097669; called by muse, mutect2, varscan2
- SEMA4C | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59691083; called by muse, mutect2, varscan2
- STIM1 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56152789; called by muse, mutect2, varscan2
- TCFL5 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1439099581; called by muse, mutect2, varscan2
- UBR1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 85/370 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51932919; called by muse, mutect2, varscan2
- USP25 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 88/398 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1484178022; called by muse, mutect2, varscan2
- ARRDC2 | c.104_120del p.L35Rfs*37 | Frame Shift Del (DEL) | VAF 31/279 reads (11%) | called by mutect2, pindel
- CTNNA2 | c.1221G>C p.K407N | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CWH43 | c.1109A>T p.K370I | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- DLX2 | c.938A>G p.H313R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2
- DMBT1 | c.2207T>C p.V736A | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- DOCK4 | c.115T>A p.C39S | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DUOX2 | c.3791G>T p.S1264I | Missense Mutation (SNP) | VAF 134/615 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- FAM163A | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 128/374 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGA | c.2285C>G p.A762G | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GC | c.568T>G p.C190G | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGCS1 | c.1474-2A>G p.X492_splice | Splice Site (SNP) | VAF 36/240 reads (15%) | called by muse, mutect2, varscan2
- KRT8 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 93/418 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP3K14 | c.1402T>G p.F468V | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MDN1 | c.3750G>T p.M1250I | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- MGAT4A | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPS28 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 77/352 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NCAM1 | c.627T>C p.N209= | Splice Region (SNP) | VAF 26/129 reads (20%) | called by muse, varscan2
- NHLRC2 | c.263del p.Y88Sfs*4 | Frame Shift Del (DEL) | VAF 34/198 reads (17%) | called by mutect2, pindel, varscan2
- NUP210L | c.1060G>T p.V354L | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR11L1 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 219/631 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- OR4M1 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 79/701 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OTUD7B | c.1448G>T p.R483L | Missense Mutation (SNP) | VAF 66/462 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCDHA5 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 155/556 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PGR | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, varscan2
- PLXND1 | c.5476A>C p.K1826Q | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN11 | c.1087-1G>T p.X363_splice | Splice Site (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2
- STRADB | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNKS1BP1 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TP63 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 116/514 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TUBA3D | c.918C>A p.D306E | Missense Mutation (SNP) | VAF 85/392 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- UPP1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- WDR47 | c.2278G>T p.A760S (on ENST00000369962 / NM_001142551.2; = p.A761S on NM_014969.5) | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAM18 | c.1572G>T p.L524= | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- ALPG | c.264G>A p.L88= | Silent (SNP) | VAF 48/290 reads (17%) | called by muse, mutect2, varscan2
- DSG4 | c.2988A>G p.L996= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV57391225; called by muse, mutect2, varscan2
- IGLV7-43 | c.324C>T p.Y108= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs768520068; called by muse, mutect2
- KMT2D | c.13161G>A p.Q4387= | Silent (SNP) | VAF 100/478 reads (21%) | called by muse, mutect2, varscan2
- LAMC1 | c.4569G>A p.Q1523= | Silent (SNP) | VAF 61/204 reads (30%) | catalogued as rs754375969; called by muse, mutect2, varscan2
- LAMC1 | c.4570C>T p.L1524= | Silent (SNP) | VAF 60/202 reads (30%) | called by muse, mutect2, varscan2
- OR1L3 | c.444C>A p.P148= | Silent (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- PCMT1 | c.156G>C p.L52= | Silent (SNP) | VAF 48/356 reads (13%) | called by muse, mutect2, varscan2
- PIK3C2B | c.2766G>A p.L922= | Silent (SNP) | VAF 73/305 reads (24%) | catalogued as COSV100916174; called by muse, mutect2, varscan2
- PINK1 | c.330C>A p.L110= | Silent (SNP) | VAF 48/434 reads (11%) | called by muse, mutect2, varscan2
- POM121L12 | c.366G>T p.G122= | Silent (SNP) | VAF 96/399 reads (24%) | catalogued as COSV101374976, COSV101375003; called by muse, mutect2, varscan2
- TBX5 | c.99G>T p.G33= | Silent (SNP) | VAF 104/464 reads (22%) | called by muse, mutect2, varscan2
- TGFB1 | c.1167C>T p.C389= | Silent (SNP) | VAF 44/156 reads (28%) | called by muse, mutect2, varscan2
- UNC13D | c.1632G>T p.V544= | Silent (SNP) | VAF 137/677 reads (20%) | catalogued as COSV52885831; called by muse, mutect2, varscan2
- ZFHX4 | c.6837G>A p.Q2279= | Silent (SNP) | VAF 86/289 reads (30%) | called by muse, mutect2, varscan2
- ACAD9 | c.*394C>T | 3'UTR (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- AK2 | c.*4185G>A | 3'UTR (SNP) | VAF 57/373 reads (15%) | called by muse, mutect2, varscan2
- AL645929.2 | chr6:29890454 A>T | 5'Flank (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- CD82 | c.336+14_336+15del | Intron (DEL) | VAF 44/234 reads (19%) | called by pindel, varscan2
- ENPEP | c.1509+361C>T | Intron (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- GABARAPL1 | c.90+15G>T | Intron (SNP) | VAF 51/246 reads (21%) | called by muse, mutect2, varscan2
- KEL | c.3+25G>A | Intron (SNP) | VAF 48/324 reads (15%) | called by muse, mutect2, varscan2
- LINC01956 | n.319G>A | RNA (SNP) | VAF 100/455 reads (22%) | called by muse, mutect2, varscan2
- LYRM9 | c.-18-321C>G | Intron (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- NAF1 | chr4:163127051 G>C | 3'Flank (SNP) | VAF 31/146 reads (21%) | called by muse, mutect2, varscan2
- PPP2R5C | c.1443+3166G>A | Intron (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1211-72C>G | Intron (SNP) | VAF 83/352 reads (24%) | called by muse, mutect2, varscan2
- TRBV25OR9-2 | n.319C>T | RNA (SNP) | VAF 50/147 reads (34%) | catalogued as rs1328304145; called by muse, mutect2, varscan2
